Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4362, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4362-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST. Specimen type: Gastrectomy. Tumor Site: Not specified. Tumor configuration: Exophytic (polypoid).
Tumor size: 12 x 7 x 5 cm. Histologic type: Adenocarcinoma. Histologic grade: Poorly differentiated. Extent of invasion: Not specified.
Lymph nodes: 4 of 8 positive for metastasis. Margins — Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin:
Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic
findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file 61723895-0184-4896-b7d0-197378b552c8 (TCGA-BR-4362.C3ABFAA0-85E5-4422-8203-87B920E9AC1C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).